Somatic mutation profile of tumor specimen TARGET-15-SJMPAL040038-09A.1 (aliquot TARGET-15-SJMPAL040038-09A.1-01D) from TARGET case TARGET-15-SJMPAL040038, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.6 years (948 days).
Specimen TARGET-15-SJMPAL040038-09A.1: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dadba731-adcd-4057-862b-3667e3ef7c58.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL040038-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL040038-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76e9aac4-95da-427f-bfe1-858f1539a49e

The open-access MAF lists 16 somatic variants for this specimen: 13 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Frame Shift Ins 1, Silent 1, 3'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 101/364 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 59/367 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.541); catalogued as rs121913250, CM136798, COSV54736487, COSV54736621, COSV54736940; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRG5 | c.1144G>A p.G382R | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758492374, COSV61082714; called by muse, mutect2, varscan2
- FRMPD3 | c.1615G>A p.V539M | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs753741770, COSV52197609; called by muse, mutect2, varscan2
- NSD3 | c.3540T>A p.D1180E | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs201732365; called by muse, mutect2, varscan2
- PCDHB8 | c.1279T>G p.L427V | Missense Mutation (SNP) | VAF 156/361 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.794); catalogued as COSV50803663; called by muse, mutect2, varscan2
- PSG11 | c.855G>T p.K285N | Missense Mutation (SNP) | VAF 148/310 reads (48%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1555756011; called by muse, mutect2, varscan2
- RPL10L | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 69/154 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.04); catalogued as COSV53560787, COSV53562301; called by muse, mutect2, varscan2
- RPL22 | c.44dup p.K16Efs*9 | Frame Shift Ins (INS) | VAF 49/128 reads (38%) | catalogued as rs759765382; called by mutect2, varscan2
- SEC24C | c.2828C>A p.T943N | Missense Mutation (SNP) | VAF 59/109 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV59541307; called by muse, mutect2, varscan2
- CACNA1S | c.3682G>A p.A1228T | Missense Mutation (SNP) | VAF 63/121 reads (52%) | SIFT tolerated (0.13); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- PIEZO1 | c.2019G>T p.E673D | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.365); called by muse, mutect2
- ZNF793 | c.829C>A p.H277N | Missense Mutation (SNP) | VAF 24/153 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NRXN1 | c.693A>T p.G231= | Silent (SNP) | VAF 8/20 reads (40%) | catalogued as COSV68052057; called by muse, mutect2, varscan2
- CYP4F8 | c.343+142C>T | Intron (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2, varscan2
- OTOA | chr16:21760567 G>T | 3'Flank (SNP) | VAF 20/265 reads (8%) | called by muse, mutect2
